Surgical pathology report (de-identified scan), TCGA case TCGA-86-7711, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-7711-01A (Primary Tumor).

[page 1 of 3]
Pathology Reports

Case ID	 Subject ID	Gross Description	Microscopic Description

[page 2 of 3]
Diagnosis Details	Comments	Formatted Path Report
	LUNG TISSUE CHECKLIST Specimen type: Lobectomy Tumor site: Lung Tumor size: 5 x 5 x 5 cm Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Not specified Other tumor nodules: No Lymph nodes: 3/3 positive for metastasis (Intrathoracical 3/3) Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None	

[page 3 of 3]
Laterality	Date of Procurement

Source: NCI Genomic Data Commons file 6eb7382c-a110-47f0-889f-2a0f902b92d3 (TCGA-86-7711.5A85D8A6-3533-4AC8-9FC9-437A81B436D6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).